Surgical pathology report (de-identified scan), TCGA case TCGA-62-A46U, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Thoraxklinik at University Hospital Heidelberg, specimen TCGA-62-A46U-01A (Primary Tumor).

Pathology Report-Summary:

Material:

lung, right, lower lobe: 14.5 x 11.0 x 6.0 cm

tumor: 4.8 x 3.5 x 3.0 cm

Diagnosis:

Adenocarcinoma mixed subtype (partially papillary, acinar, solid)

No Infiltration of pleura visceralis

pT2, pN1 (2/54), pMx, G3

ICD-O-3

adenocarcinoma, with mixed subtypes

8255/3

Site: lung, lower lobe C34.3

Pathologist:

hw
9/24/12

IIP/PA Discrepancy		
Bilateral/Synchronous Primary noted		

hw 9/24/12

Source: NCI Genomic Data Commons file 379a14ef-e540-44e6-9dc5-36382026ec8a (TCGA-62-A46U.15C4143C-779A-44D7-B75F-867E5E0F7671.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).